Somatic mutation profile of tumor specimen TCGA-IB-AAUT-01A (aliquot TCGA-IB-AAUT-01A-11D-A377-08) from TCGA case TCGA-IB-AAUT, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 65.2 years (23,801 days).
Specimen TCGA-IB-AAUT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e56bb7c7-ff4b-42b6-aaf6-fbd7392be848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUT-10A (Blood Derived Normal), aliquot TCGA-IB-AAUT-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dd5fbfd-d740-453b-b95c-0160c4fe915c

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 26/1022 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.255); called by muse, mutect2
